Gene-level copy-number profile of tumor specimen TCGA-4N-A93T-01A from TCGA case TCGA-4N-A93T, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 67.1 years (24,523 days).
Specimen TCGA-4N-A93T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.c4e3cdad-c402-447d-b7b4-b531b4791b65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4N-A93T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef1608a5-d063-4a2b-a2fa-b07b243bde6d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 17,289; copy number 2: 37,762; copy number 3: 4,642; copy number 6: 4; copy number 9: 114.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4N-A93T-01A-11D-A36W-01): tumor purity 0.85, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:23,506,184–23,586,506, 2 genes (within-gene range 0–1): NPC1, Y_RNA.
- chr18:50,823,577–51,085,045, 6 genes: RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 118 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:19,203,825–21,260,501, 118 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,902. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
